Somatic mutation profile of tumor specimen TARGET-10-PAPSPN-03A (aliquot TARGET-10-PAPSPN-03A-01D) from TARGET case TARGET-10-PAPSPN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.4 years (4,173 days).
Specimen TARGET-10-PAPSPN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91bce2a5-8580-4fdf-b6b1-d4de709c31a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPSPN-10A (Blood Derived Normal), aliquot TARGET-10-PAPSPN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f9c7d81-c63a-4457-ba52-5b34cdf4cc78

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Splice Site 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>C p.R683S | Missense Mutation (SNP) | VAF 168/404 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 167/350 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CENPE | c.2947C>A p.L983I | Missense Mutation (SNP) | VAF 282/710 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV54387629; called by muse, varscan2
- CSF1R | c.2839T>C p.S947P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs923332469; called by muse, mutect2
- ELAVL2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 281/601 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV56368591; called by muse, mutect2, varscan2
- ERMARD | c.1394+1G>A p.X465_splice | Splice Site (SNP) | VAF 71/152 reads (47%) | catalogued as rs781250225, COSV64648061; called by muse, mutect2, varscan2
- MYH7B | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1490035894, COSV53419849; called by muse, mutect2, varscan2
- NPEPPS | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs766039929, COSV59104656; called by muse, mutect2, varscan2
- PRKN | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs749768565, COSV100627580, COSV58224511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1340763076, COSV59451869; called by muse, mutect2, varscan2
- SRRT | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs755711164, COSV53815232, COSV53818748; called by muse, mutect2, varscan2
- UGT2A3 | c.227T>A p.V76E | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV52361655; called by muse, mutect2, varscan2
- CAPN5 | c.1608G>A p.R536= (on ENST00000456580; = p.R496= on NM_004055.5) | Splice Region (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PAX5 | c.295dup p.I99Nfs*3 | Frame Shift Ins (INS) | VAF 88/231 reads (38%) | called by mutect2, pindel, varscan2
- NOBOX | c.480G>A p.P160= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs368119264; called by muse, mutect2
- RFPL4B | c.348C>T p.S116= | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as rs147620371, COSV71437811; called by muse, mutect2, varscan2
- SAMD13 | c.315C>T p.Y105= (on ENST00000370671; = p.Y99= on NM_001010971.3) | Silent (SNP) | VAF 212/485 reads (44%) | catalogued as rs374324643, COSV65744540; called by muse, mutect2, varscan2
- IGLV5-45 | chr22:22376505 ins TC | 3'Flank (INS) | VAF 41/81 reads (51%) | called by mutect2, pindel, varscan2
